CPTAC case C3L-07033 — Pancreas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/39e5a08f-a9bc-4d5a-b51f-1179c42e8ffe

Demographics
Sex at birth: male; Race: white; Year of birth: 1947.

Other clinical attributes
- Weight: 73.6 kg; Height: 170 cm; BMI: 25.47.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (1 sample)
- Sample C3L-07033-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 50 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
